Gene-level copy-number profile of tumor specimen TCGA-FC-A4JI-01A from TCGA case TCGA-FC-A4JI, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 71.0 years (25,931 days).
Specimen TCGA-FC-A4JI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.40bfa491-7667-4b80-935b-dd0ce559e001.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FC-A4JI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 831 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c294635e-17bb-4ffe-927d-2fda395df8e2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 2,703; copy number 2: 12,982; copy number 3: 22,971; copy number 4: 13,957; copy number 5: 2,523; copy number 6: 2,490; copy number 7: 827; copy number 8: 667; copy number 9: 160; copy number 10: 284; copy number 11: 84; copy number 12: 39; copy number 13: 35; copy number 14: 42; copy number 20: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FC-A4JI-01A-11D-A256-01): tumor purity 0.65, ploidy 3.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:117,023,918–117,027,024, 3 genes: MTND1P28, MTND2P21, MTCO1P43.
- chr2:132,345,616–132,646,582, 7 genes (within-gene range 0–2): AC097532.2, AC097532.3, FAM201B, RNU6-175P, GPR39, YBX1P7, RN7SKP103.
- chr2:139,323,921–139,669,305, 5 genes: AC013265.1, AC062021.1, AC016710.1, SNORA72, MRPS18BP2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,122 genes in 64 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:127,915,232–129,520,507, 60 genes, copy number 7 (within-gene range 5–7): KBTBD12, RNA5SP139, SEC61A1, RUVBL1, RNU2-37P, RUVBL1-AS1, RNU6-823P, EEFSEC, AL449214.1, DNAJB8, DNAJB8-AS1, GATA2, GATA2-AS1, TMED10P2, AC080005.1, LINC01565, RPN1, Metazoa_SRP, POU5F1P6, RAB7A, AC079945.1, MARK2P8, FTH1P4, RN7SL698P, RPS15AP16, MARK2P17, MARK3P3, MARK2P6, AC112484.3, AC112484.1, AC112484.2, AC112484.5, ACAD9, CFAP92, AC112484.4, EFCC1, AC108673.1, GP9, RAB43, ISY1-RAB43, AC108673.2, ISY1, AC108673.3, CNBP, RPS27P12, COPG1, MIR6826, AC137695.3, HMCES, H1-10, H1-10-AS1, NUP210P3, AC137695.1, AC137695.2, AL449212.1, RPL32P3, SNORA7B, EFCAB12, MBD4, IFT122.
- chr3:149,648,997–155,294,176, 102 genes, copy number 8–10 (broad region; genes not listed).
- chr3:176,415,439–184,150,435, 152 genes, copy number 10–20 (broad region; genes not listed).
- chr7:139,198,557–141,812,257, 67 genes, copy number 8 (broad region; genes not listed).
- chr8:2,033,508–2,512,580, 6 genes, copy number 7 (within-gene range 2–7): AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2.
- chr8:34,784,028–40,897,833, 113 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:41,803,349–47,202,897, 90 genes, copy number 7 (broad region; genes not listed).
- chr8:48,294,026–49,076,093, 19 genes, copy number 10: IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC100805.1, AC013701.1, SNAI2, AC013701.2, AC044893.2, PPDPFL.
- chr8:49,740,216–53,162,987, 31 genes, copy number 7–11: PSAT1P1, AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1, NPBWR1, AC009800.1, AC009646.1.
- chr8:53,225,724–55,826,445, 43 genes, copy number 8–11 (within-gene range 4–11): OPRK1, AC131902.1, AC022034.3, AC131902.2, AC022034.1, AC022034.4, AC022034.2, MAPK6P1, AC103778.1, ATP6V1H, RGS20, AC113194.1, RPS27AP13, RNU6-1331P, TCEA1, AC100821.1, AC100821.2, LYPLA1, TDGF1P5, Metazoa_SRP, MRPL15, RNU6ATAC32P, AC060764.1, AC044836.1, RNU105C, AC027250.1, AC027250.2, RN7SL250P, SOX17, AC091076.1, TRMT112P7, RP1, SEC11B, AC090151.1, AC084834.1, XKR4, AC022679.2, AC022679.1, SBF1P1, AC090200.1, TMEM68, RNA5SP265, TGS1.
- chr8:56,588,385–57,244,793, 7 genes, copy number 8 (within-gene range 5–8): RPL37P6, AC009597.1, AC009597.2, RNU6-13P, BPNT2, RNA5SP266, LINC01606.
- chr8:57,492,884–58,272,450, 12 genes, copy number 8 (within-gene range 5–8): AC090796.1, AC104051.1, AC104051.2, LINC01602, AC012103.1, FAM110B, AC104350.1, AC027698.1, RPL26P26, AC092819.3, AC092819.1, AC092819.2.
- chr8:60,046,755–60,664,530, 9 genes, copy number 9: AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2.
- chr8:61,500,556–61,765,969, 5 genes, copy number 8: ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1.
- chr8:62,855,068–63,039,407, 5 genes, copy number 7: XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2.
- chr8:63,586,000–67,196,778, 61 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr8:68,176,768–71,592,025, 48 genes, copy number 7 (within-gene range 4–7): AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, AC120194.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1, EYA1.
- chr8:72,019,917–72,950,445, 12 genes, copy number 8–12: TRPA1, AC078906.1, AC022905.1, RNA5SP271, AC124293.1, AC011131.1, KCNB2, HAUS1P3, AC013562.2, AC013562.1, AC090735.1, AC022893.2.
- chr8:73,651,289–73,972,287, 9 genes, copy number 7 (within-gene range 4–7): VENTXP6, AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, AC022868.1, GYG1P1, ELOC.
- chr8:79,571,153–82,961,926, 72 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr8:91,909,738–95,993,103, 85 genes, copy number 7–12 (broad region; genes not listed).
- chr8:97,853,021–98,294,393, 13 genes, copy number 10: AP002906.1, SUMO2P18, RPS23P1, MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1, NIPAL2, RNU6-914P.
- chr8:98,391,401–98,463,050, 5 genes, copy number 10: AP003355.3, AP003355.1, KCNS2, AP003355.2, RNU6-748P.
- chr8:99,527,826–103,002,424, 93 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:103,371,538–104,467,055, 15 genes, copy number 8 (within-gene range 4–8): CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1, RIMS2, PTMAP15, AC007751.1, AC090686.1, DPYS, DCSTAMP.
- chr8:105,142,860–106,752,694, 14 genes, copy number 8 (within-gene range 5–8): AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1.
- chr8:107,899,316–109,537,207, 17 genes, copy number 9 (within-gene range 4–9): RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1.
- chr8:116,642,130–117,176,714, 9 genes, copy number 7 (within-gene range 4–7): EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1.
- chr8:118,923,557–120,373,573, 26 genes, copy number 7–11 (within-gene range 4–11): TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1.
- chr8:121,954,640–127,419,050, 100 genes, copy number 7–10 (within-gene range 4–11) (broad region; genes not listed).
- chr8:127,072,694–128,564,679, 26 genes, copy number 11: CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr8:129,748,196–130,443,674, 15 genes, copy number 8 (within-gene range 4–8): GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1.
- chr8:133,191,039–135,742,495, 42 genes, copy number 7–11: CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P.
- chr8:139,460,062–142,185,527, 43 genes, copy number 7 (within-gene range 4–7): AC087354.1, AC090093.1, KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.2, AC138647.1, AC025839.1, MIR1302-7, AC104417.1, AC104417.2, AC103758.1.
- chr8:143,157,914–144,444,440, 93 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr11:67,266,473–70,436,584, 128 genes, copy number 9–13 (within-gene range 5–13) (broad region; genes not listed).
- chr13:20,956,179–23,897,502, 63 genes, copy number 7 (broad region; genes not listed).
- chr18:47,390–5,630,700, 117 genes, copy number 7 (broad region; genes not listed).
- chr18:10,525,905–11,670,165, 28 genes, copy number 7: NAPG, AP001099.1, LINC01887, AP001180.3, CCDC58P1, AP001180.2, AP001180.5, PMM2P1, AP001180.1, PIEZO2, AP001180.4, KIAA0895LP1, MIR6788, AP005120.1, AP005139.1, AP005229.1, AP005229.2, AP001109.1, LINC01928, LINC01255, AP001017.1, SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, MIR7153, AP001120.1.
- chr21:10,328,411–26,967,088, 225 genes, copy number 8–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 350. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
